Somatic mutation profile of tumor specimen PCProject_0036_T1_WES (aliquot PCProject_0036_T1_WES_1) from CMI case PCProject_0036, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.4 years (22,779 days).
Specimen PCProject_0036_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab0b85a9-5d7b-45bf-8654-125a28a9f07c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0036_SALIVA (Saliva), aliquot PCProject_0036_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e62e5244-ca3f-4a41-be34-0c17abeacc17

The open-access MAF lists 44 somatic variants for this specimen: 29 protein-altering or splice-affecting, 4 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Intron 6, Silent 4, Frame Shift Del 3, 3'UTR 3, Nonsense Mutation 2, RNA 1, Frame Shift Ins 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY9 | c.398A>C p.Y133S | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV53578994, COSV53583030; called by muse, mutect2, varscan2
- ANAPC5 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV55842371; called by muse, mutect2
- EPHA3 | c.1048G>C p.D350H | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60700651; called by muse, varscan2
- GGT1 | c.1495G>A p.V499M | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs775363985; called by muse, varscan2
- GPR6 | c.110del p.G37Dfs*8 | Frame Shift Del (DEL) | VAF 17/50 reads (34%) | catalogued as COSV51570948; called by pindel, varscan2
- KLHL11 | c.1253G>A p.G418E | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as COSV59862944; called by muse, mutect2, varscan2
- RAPGEF4 | c.271A>C p.K91Q | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.761); catalogued as rs762710055; called by muse, mutect2, varscan2
- RAPGEF5 | c.375-2A>G p.X125_splice (on ENST00000401957 / NM_001367602.2; = p.X428_splice on NM_012294.5) | Splice Site (SNP) | VAF 48/158 reads (30%) | catalogued as COSV59790963; called by muse, mutect2, varscan2
- REM1 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369078506; called by muse, varscan2
- TANC1 | c.2776G>A p.V926M | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs774995611, COSV99715325; called by muse, mutect2, varscan2
- TPMT | c.409G>C p.D137H | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs376217758; called by muse, varscan2
- TRPC3 | c.762G>A p.M254I (on ENST00000379645 / NM_001366479.2; = p.M181I on NM_003305.2) | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1480352014; called by muse, mutect2, varscan2
- ZC3H3 | c.1753G>A p.G585R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.161); catalogued as rs772856401; called by muse, mutect2
- ADRM1 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
- ARAP3 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATXN1L | c.1433C>G p.A478G | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- CACNA2D2 | c.401T>G p.L134R | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNHD1 | c.2050G>T p.D684Y | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- FOXA1 | c.798_817delinsA p.F266Lfs*49 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | called by pindel, varscan2*
- MUC4 | c.4996C>A p.P1666T | Missense Mutation (SNP) | VAF 62/493 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.65); called by muse, varscan2
- NKD1 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OLIG1 | c.685T>A p.C229S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POTEB3 | c.306C>A p.C102* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | called by mutect2, varscan2
- PPP1R12A | c.1564T>G p.L522V | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RELN | c.2059C>G p.H687D | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0.001); called by muse, mutect2
- SMIM3 | c.69dup p.V24Cfs*34 | Frame Shift Ins (INS) | VAF 51/145 reads (35%) | called by mutect2, pindel, varscan2
- STAT1 | c.1082A>G p.K361R | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- SYNE2 | c.10621G>A p.V3541I | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRPM8 | c.2279del p.F760Sfs*24 | Frame Shift Del (DEL) | VAF 75/222 reads (34%) | called by mutect2, pindel, varscan2
- EDAR | c.600C>T p.I200= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs901116756, COSV99303193; called by muse, mutect2, varscan2
- GUCY1A1 | c.405T>G p.S135= | Silent (SNP) | VAF 8/18 reads (44%) | called by muse, varscan2
- ITPRIPL2 | c.1455C>T p.D485= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV67347892; called by muse, mutect2, varscan2
- KRT6C | c.108C>A p.I36= | Silent (SNP) | VAF 22/186 reads (12%) | called by muse, mutect2, varscan2
- AC108676.1 | n.203T>C | RNA (SNP) | VAF 6/42 reads (14%) | catalogued as rs1169048224; called by muse, mutect2
- AMPH | c.1182+1346T>C | Intron (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
- ATP11A | c.*62_*64delinsTT | 3'UTR (DEL) | VAF 39/188 reads (21%) | called by pindel, varscan2*
- C3orf33 | c.115-1546A>G | Intron (SNP) | VAF 6/39 reads (15%) | catalogued as rs1189235651; called by muse, mutect2
- GATA4 | chr8:11761554 T>C | 3'Flank (SNP) | VAF 5/48 reads (10%) | called by muse, varscan2
- MBD3 | c.*2898A>G | 3'UTR (SNP) | VAF 5/17 reads (29%) | called by muse, varscan2
- NLRP2 | c.281-393A>G | Intron (SNP) | VAF 4/24 reads (17%) | catalogued as rs752108162; called by muse, varscan2
- PPA2 | c.656-6675T>C | Intron (SNP) | VAF 36/119 reads (30%) | called by muse, mutect2, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 17/162 reads (10%) | catalogued as rs910081914; called by muse, mutect2
- RPL34 | c.*1A>C | 3'UTR (SNP) | VAF 25/96 reads (26%) | called by muse, mutect2, varscan2
- SPINT2 | c.391+51G>A | Intron (SNP) | VAF 6/47 reads (13%) | catalogued as rs749337905; called by mutect2, varscan2
